Somatic mutation profile of tumor specimen TCGA-86-6562-01A (aliquot TCGA-86-6562-01A-11D-1753-08) from TCGA case TCGA-86-6562, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.8 years (19,301 days).
Specimen TCGA-86-6562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 851a3caf-f287-4d2b-b61b-c03e6c0358c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-6562-10A (Blood Derived Normal), aliquot TCGA-86-6562-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d69eb0c-4110-48f6-a540-0a14a1fab3c1

The open-access MAF lists 54 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 4, Splice Region 1, Splice Site 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.3337C>T p.P1113S | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV60911680; called by muse, mutect2, varscan2
- AKAP6 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs915697862, COSV99801791; called by mutect2, varscan2
- AKAP9 | c.8287C>T p.H2763Y (on ENST00000359028; = p.H2739Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV62342344; called by muse, mutect2, varscan2
- AQP9 | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1250304680, COSV54968079; called by muse, mutect2, varscan2
- ATAD3B | c.207T>C p.R69= | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100426519; called by muse, mutect2
- BTG2 | c.196C>G p.R66G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99305824, COSV99306043; called by muse, mutect2, varscan2
- CNTNAP4 | c.2369C>A p.S790* | Nonsense Mutation (SNP) | VAF 53/157 reads (34%) | catalogued as COSV56672893; called by muse, mutect2, varscan2
- CXXC4 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV67296142; called by muse, mutect2, varscan2
- EML4 | c.397C>G p.H133D | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.057); catalogued as rs1382636234, COSV59295742, COSV59300836; called by muse, mutect2
- ERBB2 | c.2326_2327insTCT p.G776delinsVC | In Frame Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs397516979, COSV54064203, COSV54064477, COSV54066307, COSV54066802, COSV54077015, COSV99507093; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ESRRG | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.47); catalogued as rs774655818, COSV63155622; called by muse, mutect2, varscan2
- FHOD1 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50759616; called by muse, mutect2, varscan2
- GTF3C3 | c.2629C>G p.Q877E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs746793388, COSV55831579; called by muse, mutect2
- HSD3B1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs1402470477, COSV104376572, COSV52490114; called by muse, mutect2, varscan2
- KIF3C | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); catalogued as rs199957407, COSV53098587; called by mutect2, varscan2
- KRT71 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs778601047, COSV57288926; called by muse, mutect2, varscan2
- PAN3 | c.2320-1G>T p.X774_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV56702044; called by muse, mutect2, varscan2
- PDE11A | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 15/163 reads (9%) | catalogued as COSV61773969; called by muse, mutect2
- PPRC1 | c.3446C>A p.P1149Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs977570296, COSV53384226; called by muse, mutect2, varscan2
- PSTPIP2 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV101297358; called by muse, mutect2, varscan2
- RIC8A | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1178941769, COSV100254852; called by muse, mutect2
- SEPTIN12 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs774632312, COSV51615526, COSV51615955; called by muse, mutect2, varscan2
- SERPINB7 | c.462C>G p.I154M | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60533193, COSV60536188; called by muse, mutect2
- SETDB1 | c.920A>T p.Q307L | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54979908; called by muse, mutect2
- SHPRH | c.4679G>A p.R1560H (on ENST00000275233 / NM_001042683.3; = p.R1564H on NM_173082.3) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as rs375643591, COSV51608973; called by muse, mutect2
- SMTN | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV60776708; called by muse, mutect2, varscan2
- SPPL3 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62231854; called by muse, mutect2
- SSH2 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52169119; called by muse, mutect2, varscan2
- SSX7 | c.25A>G p.R9G | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV53339648; called by muse, mutect2
- SUPT6H | c.950C>G p.A317G | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV58925948; called by muse, mutect2, varscan2
- TRPM6 | c.5963A>G p.E1988G | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62506164; called by muse, mutect2, varscan2
- TUBD1 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as COSV56676115; called by muse, mutect2, varscan2
- UACA | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59854078, COSV59854605; called by muse, mutect2, varscan2
- UACA | c.2011C>A p.L671I | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV59854619; called by muse, mutect2, varscan2
- VCP | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV62720029; called by muse, mutect2, varscan2
- XCL2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs1177960058, COSV63194111; called by muse, mutect2
- ZFYVE9 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV55092252; called by muse, mutect2, varscan2
- ZNF451 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); catalogued as COSV100675038, COSV62600010; called by muse, mutect2, varscan2
- AKAP3 | c.2504A>C p.E835A | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- TRGV4 | c.149A>T p.Y50F | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRGV9 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2
- ACACB | c.6564C>A p.P2188= | Silent (SNP) | VAF 73/155 reads (47%) | catalogued as COSV58131239; called by muse, mutect2, varscan2
- ADCY10 | c.2760G>C p.V920= | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as COSV100896589, COSV63239468; called by muse, mutect2
- FRYL | c.6129G>A p.K2043= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV51943748; called by muse, mutect2
- GABBR2 | c.2814C>G p.V938= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV52299009; called by muse, mutect2, varscan2
- GPRASP2 | c.276A>G p.G92= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV59990738; called by muse, mutect2, varscan2
- OR5M1 | c.420C>T p.I140= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs780639637, COSV73202023, COSV73202103; called by muse, mutect2, varscan2
- ORAI2 | c.393G>A p.L131= | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as COSV100709940; called by muse, mutect2
- PRAMEF14 | c.987C>T p.Y329= | Silent (SNP) | VAF 46/164 reads (28%) | catalogued as rs1296018648, COSV100577275; called by muse, mutect2, varscan2
- PSTPIP2 | c.579G>C p.L193= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV101297359; called by muse, mutect2, varscan2
- TFCP2 | c.795T>C p.Y265= | Silent (SNP) | VAF 102/316 reads (32%) | catalogued as rs762413238, COSV56932236; called by muse, varscan2
- TMEM104 | c.678C>T p.D226= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs368435149; called by muse, mutect2, varscan2
- WT1 | c.525C>G p.G175= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV60069430, COSV60084148; called by muse, mutect2, varscan2
- SPAG7 | c.-2A>C | 5'UTR (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99236617; called by muse, mutect2, varscan2
